Surgical pathology report (de-identified scan), TCGA case TCGA-XM-A8RG, project TCGA-THYM (Thymoma), tissue source site MSKCC, specimen TCGA-XM-A8RG-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED] Accession #: [REDACTED]
MRN: [REDACTED] Service: [REDACTED]
Account #: [REDACTED] Date of Procedure: [REDACTED]
[REDACTED] (Age: [REDACTED] M Date of Receipt: [REDACTED]
Physician: [REDACTED] Date of Report: [REDACTED]
CC: [REDACTED]
Patient Address: [REDACTED]

....

Clinical Diagnosis & History:
Ant. mediastinal mass

Specimens Submitted:
1: Thymus (fs)

DIAGNOSIS:

1. Thymus (fs):
- Thymoma, type A (4.0 cm) (see note)
- No capsular invasion identified
- No lymphovascular invasion identified
- Surgical margins are negative for tumor

Note: Immunohistochemistry for pan-cytokeratin AE1/AE3 is diffusely positive, consistent with the diagnosis. Only scattered Tdt-positive lymphocytes are seen. CD1a is positive mainly in dendritic cells.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received fresh for frozen section consultation, labeled "Thymus", and consists of a 30.5 g, 9.0 x 4.5 x 2.5 cm tan-pink rubbery portion of tissue with attached adipose tissue. The thymus measures 2.0 x 1.5 x 1.5 cm. The specimen is inked purple and serially sectioned to reveal a tan-white homogenous rubbery nodule measuring 4.0 x 3.0 x 2.1 cm. A representative section is submitted for TFS and frozen section control. The remaining specimen is representatively submitted.

** Continued on next page **

ICD O-3
Thymoma, type A, NOS 8581/1
Site Thymus C879
203/12/14

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

Patient:

MRN:

Account #:

Accession #:

Physician:

Service: Thoracic

Date of Report:

Page 2 of 2

Summary of sections:

FSC1_1-frozen section control

U-undesignated

Summary of Sections:

Part 1: Thymus (fs)

Blocks	Block Designation	PCs
1	{not entered}	
5	U 5	

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: Thymoma
PERMANENT DIAGNOSIS: Same

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: Thymoma
PERMANENT DIAGNOSIS: Same

** End of Report **

Source: NCI Genomic Data Commons file 398a2354-7927-42ed-99bc-b954235f040c (TCGA-XM-A8RG.0C55F447-1FC4-4DB4-B554-29ABBB8F3AB3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).